TCGA case TCGA-RZ-AB0B — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Wills Eye Institute. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2bf47a88-df0a-4102-af2e-998c3d252b9c

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 47 years; Vital status: Dead; Days to death: 149 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Mixed epithelioid and spindle cell melanoma: ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.80; Tissue or organ of origin: Overlapping lesion of eye and adnexa; Site of resection or biopsy: Overlapping lesion of eye and adnexa; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.0 years (17,514 days); Year of diagnosis: 2013; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical N: NX; AJCC clinical M: MX; AJCC clinical stage: Stage IV; AJCC pathologic T: T4b; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Distant Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 149 days; Sites of involvement: Eye, Choroid / Eye, Ciliary Body / Liver.
   Pathology details: Epithelioid cell percent range: >90%; Measurement type: Pathologic; Tumor depth measurement: 12.7.

Follow-up (1 entry)
- Days to follow up: 149 days; Disease response: Tumor Free.

Other clinical attributes
- Eye color: Blue.
- Timepoint category: Initial Diagnosis; Weight: 186 kg; Height: 157.48 cm; BMI: 75.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RZ-AB0B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-RZ-AB0B-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RZ-AB0B-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RZ-AB0B-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Cause of death: Metastatic Uveal Melanoma.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Choroid; Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell; Tumor morphology percentage: >90%.
- Primary pathology: Tumor thickness measurement: Pathologic Measurement.
- Primary pathology, Metastatic site list: Metastasis site: Liver.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 149 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 149 days; progression-free interval: no event (censored), 149 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RZ-AB0B-01A-11D-A39V-01): tumor purity 0.93, ploidy 2.08, whole-genome doublings 0.
